Somatic mutation profile of tumor specimen MMRF_1859_1_BM_CD138pos (aliquot MMRF_1859_1_BM_CD138pos_T1_KBS5U_L05554) from MMRF case MMRF_1859, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,107 days).
Specimen MMRF_1859_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58336d48-7f00-41f5-9aa7-dc29055e4426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1859_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1859_1_PB_Whole_C3_KBS5U_L05575; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a39dbb92-248c-4805-8a87-f95d4cd99b55

The open-access MAF lists 145 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 47, Missense Mutation 42, Silent 20, Intron 10, Nonsense Mutation 7, 5'UTR 7, Frame Shift Del 4, 3'Flank 2, Splice Site 2, RNA 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.2806C>T p.R936* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as rs121908390, CM001120, COSV61097015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSP | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as rs1561693779; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALLC | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 80/168 reads (48%) | catalogued as rs753867733, COSV52996314; called by muse, mutect2, varscan2
- CACNA2D3 | c.1959G>A p.W653* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | catalogued as rs369774739; called by muse, mutect2, varscan2
- EPHA10 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as rs775871085; called by muse, mutect2, varscan2
- IGKV2-28 | c.63T>A p.D21E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs755906046; called by muse, varscan2
- KAAG1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.634); catalogued as rs1192251469, COSV99219666; called by muse, mutect2, varscan2
- KIF24 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs916643091; called by muse, mutect2, varscan2
- MARK4 | c.2082C>G p.F694L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99488924; called by muse, mutect2, varscan2
- NINL | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as COSV53999410; called by muse, mutect2
- NLRP3 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.123); catalogued as COSV60226425; called by muse, mutect2, varscan2
- OR13C4 | c.647del p.F216Sfs*30 | Frame Shift Del (DEL) | VAF 33/223 reads (15%) | catalogued as rs752116520, COSV52927828; called by mutect2, pindel, varscan2
- OR5AN1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1056756621, COSV58321865, COSV58322176; called by muse, mutect2
- PCDH15 | c.5824G>A p.E1942K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs200913448, COSV100227946; called by muse, mutect2, varscan2
- POM121L12 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs777785485, COSV101374905, COSV68693279, COSV68694022; called by muse, mutect2, varscan2
- RIF1 | c.5842_5846del p.R1948* | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs750886550; called by mutect2, pindel, varscan2
- SLC2A4 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs148284992; called by muse, mutect2, varscan2
- STXBP5 | c.2859G>T p.L953F (on ENST00000321680 / NM_001127715.2; = p.L917F on NM_139244.4) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV51649639, COSV51651850; called by muse, mutect2, varscan2
- TNIK | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs748077043, COSV99460263; called by muse, mutect2, varscan2
- ZNF578 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs760030665; called by muse, mutect2, varscan2
- ACACB | c.5015C>A p.S1672Y | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADAM8 | c.1316C>T p.T439I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAMTS2 | c.2738G>A p.C913Y | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ANGEL2 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARSL | c.385T>G p.F129V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- BMP10 | c.575A>C p.Y192S | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- C12orf29 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C6 | c.1169-2A>T p.X390_splice | Splice Site (SNP) | VAF 92/185 reads (50%) | called by muse, mutect2, varscan2
- CD101 | c.71dup p.T25Nfs*9 | Frame Shift Ins (INS) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- CUL9 | c.3156+1G>A p.X1052_splice | Splice Site (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- DMD | c.10312G>A p.E3438K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOP1A | c.3766A>T p.I1256L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFRA3 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXA2 | c.569G>A p.W190* | Nonsense Mutation (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- IGHV1-3 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, varscan2
- ITPRIPL2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LRBA | c.5791G>C p.D1931H | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MTMR7 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.363); called by muse, mutect2
- NEGR1 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUP107 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- OBSL1 | c.3673G>A p.G1225S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- OR4A47 | c.235T>A p.L79M | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PARD6G | c.808T>A p.S270T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEX1 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PEX11B | c.384G>C p.L128F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.104); called by muse, mutect2
- PIEZO2 | c.1921A>G p.K641E | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHF2 | c.611G>C p.C204S | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTP4A1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SEC24C | c.1810C>G p.Q604E | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SLC16A1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- SLC38A2 | c.101A>C p.Q34P | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, varscan2
- SLC39A11 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- TENT5C | c.686_687del p.R229Tfs*54 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- TMEM131 | c.3836A>G p.K1279R | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TP53BP1 | c.1594A>C p.S532R | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TTC39B | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 26/446 reads (6%) | called by muse, mutect2
- USP7 | c.2209del p.E737Kfs*6 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ATCAY | c.162C>T p.N54= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs373392142; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CARS2 | c.471C>A p.L157= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- COQ4 | c.675C>T p.N225= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs1184282546; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDIT4L | c.234C>T p.V78= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs779530118, COSV56767696; called by muse, varscan2
- DNAH10 | c.8577C>T p.H2859= (on ENST00000409039; = p.H2798= on NM_207437.3) | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs1201699370; called by muse, mutect2, varscan2
- EPB41L3 | c.2032C>T p.L678= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- ESCO1 | c.1104T>C p.S368= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- FCGBP | c.11712C>T p.G3904= | Silent (SNP) | VAF 27/214 reads (13%) | catalogued as rs371201195; called by muse, mutect2, varscan2
- FURIN | c.1458C>T p.H486= | Silent (SNP) | VAF 121/157 reads (77%) | catalogued as rs376410361, COSV51580065; called by muse, mutect2, varscan2
- IGLV3-1 | c.309C>T p.D103= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs148659796; called by muse, mutect2, varscan2
- JMJD1C | c.4626T>C p.S1542= | Silent (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- KCNC3 | c.1710C>A p.G570= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- KIF26A | c.2556C>T p.D852= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as rs563689633, COSV59468841; called by muse, mutect2, varscan2
- RBBP7 | c.904C>T p.L302= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SECISBP2L | c.1296T>A p.T432= (on ENST00000559471 / NM_001193489.2; = p.T387= on NM_014701.4) | Silent (SNP) | VAF 32/279 reads (11%) | called by muse, mutect2, varscan2
- SEMA4F | c.783C>T p.Y261= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs146708517; called by muse, mutect2, varscan2
- SLC16A13 | c.462A>G p.T154= | Silent (SNP) | VAF 60/162 reads (37%) | called by muse, mutect2, varscan2
- TMPRSS2 | c.156C>T p.Y52= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as rs560639139; called by muse, mutect2, varscan2
- TRPM8 | c.36C>T p.N12= | Silent (SNP) | VAF 36/291 reads (12%) | called by muse, mutect2, varscan2
- UGT1A7 | c.738C>T p.S246= | Silent (SNP) | VAF 68/249 reads (27%) | called by muse, mutect2, varscan2
- A2ML1 | c.483+36T>C | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- AC009093.9 | n.28T>C | RNA (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- AGBL2 | c.287-96C>T | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as rs1324128622; called by mutect2, varscan2
- ALDH18A1 | c.*601T>A | 3'UTR (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- ANKRD13B | c.*390C>T | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- APPL2 | c.*935_*943del | 3'UTR (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel*
- CLEC4G | c.-65C>T | 5'UTR (SNP) | VAF 55/101 reads (54%) | catalogued as rs751324079, COSV61003201; called by muse, mutect2, varscan2
- CLN8 | c.*4081T>A | 3'UTR (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- CMTR2 | c.*718A>G | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- DLGAP1 | c.*343C>A | 3'UTR (SNP) | VAF 22/71 reads (31%) | catalogued as rs573096590; called by muse, mutect2, varscan2
- DNHD1 | c.-125T>C | 5'UTR (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- DPAGT1 | c.-1418C>G | 5'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2
- DPP10 | c.*2194T>C | 3'UTR (SNP) | VAF 11/76 reads (14%) | catalogued as rs1441592553; called by muse, mutect2, varscan2
- ENTPD5 | c.*838del | 3'UTR (DEL) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- EXOC6B | c.1980+3231_1980+3232del | Intron (DEL) | VAF 18/54 reads (33%) | called by pindel, varscan2
- FOXK2 | c.*427G>A | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- GIPR | c.73-80G>A | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- GRB10 | c.*391C>A | 3'UTR (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- GRIN2A | c.*4398C>T | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- GRM4 | c.*798G>A | 3'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs541756238; called by mutect2, varscan2
- IGF1R | c.*1074T>C | 3'UTR (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- ISCA2 | c.*1843C>T | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs116065316; called by muse, mutect2, varscan2
- KCNB2 | c.-21T>C | 5'UTR (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- KLHL1 | c.-624A>C | 5'UTR (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- LINC01550 | n.180C>G | RNA (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- LRATD1 | c.*1135C>T | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- LRRC8B | c.*4649A>G | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- LY9 | c.454+2493T>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- MAP2K5 | c.-342C>T | 5'UTR (SNP) | VAF 140/634 reads (22%) | called by muse, mutect2, varscan2
- MAT1A | c.*1614G>A | 3'UTR (SNP) | VAF 37/94 reads (39%) | catalogued as rs1201725281; called by muse, mutect2, varscan2
- MATR3 | c.*1500A>C | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- NAV3 | c.*623C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- NLGN1 | c.*152del | 3'UTR (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- NOTO | c.*1171C>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- NPAP1 | c.*1750C>T | 3'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- NT5C3A | c.*27dup | 3'UTR (INS) | VAF 50/351 reads (14%) | called by mutect2, pindel, varscan2
- OPCML | c.*259G>A | 3'UTR (SNP) | VAF 25/41 reads (61%) | catalogued as rs1325815306; called by muse, mutect2, varscan2
- PDCD6IP | c.*648C>T | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- PIFO | c.*535T>C | 3'UTR (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2, varscan2
- PIPOX | c.*400C>A | 3'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as rs1009755577; called by muse, varscan2
- PMS1 | c.1856+2281G>A | Intron (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- POLE | c.1106+47G>A | Intron (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- PRSS16 | c.-7G>A | 5'UTR (SNP) | VAF 8/66 reads (12%) | catalogued as rs770555613, COSV100041522; called by muse, mutect2, varscan2
- PSAPL1 | c.*1343C>T | 3'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- PTGS2 | c.*2077C>T | 3'UTR (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
- PXDN | c.*2302C>T | 3'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2
- RNF169 | c.*1699T>G | 3'UTR (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- RRAS2 | c.*135C>G | 3'UTR (SNP) | VAF 68/357 reads (19%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-3325G>T | Intron (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- SGCB | c.*764C>A | 3'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- SLC26A9 | c.553-52C>T | Intron (SNP) | VAF 19/64 reads (30%) | catalogued as rs776252236; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827837 T>A | 3'Flank (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- SORCS3 | c.*1557G>A | 3'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as rs1179632131; called by muse, mutect2, varscan2
- SP6 | c.*759G>A | 3'UTR (SNP) | VAF 10/84 reads (12%) | catalogued as rs1051324545; called by muse, mutect2, varscan2
- SPRY3 | c.*5327T>C | 3'UTR (SNP) | VAF 71/390 reads (18%) | catalogued as rs889214042; called by muse, mutect2, varscan2
- SRSF10 | c.*5872G>A | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- THAP2 | c.*3322T>G | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- TMEM154 | c.*5897T>A | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- TMEM72 | c.*552C>T | 3'UTR (SNP) | VAF 27/67 reads (40%) | catalogued as rs992072240; called by muse, mutect2, varscan2
- TP53INP2 | c.*236C>A | 3'UTR (SNP) | VAF 117/236 reads (50%) | called by muse, mutect2, varscan2
- TSC1 | c.*2947A>C | 3'UTR (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- TTYH3 | c.*1725G>A | 3'UTR (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- UBP1 | chr3:33388459 G>C | 3'Flank (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8793G>A | 3'UTR (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- VWA1 | c.*327C>T | 3'UTR (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- WNK2 | c.6371-82G>A | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs925348707, COSV52934635; called by muse, mutect2
- ZNF568 | c.*462C>A | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- ZNF681 | c.*2906G>A | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
